Gene-level copy-number profile of tumor specimen TCGA-33-4533-01A from TCGA case TCGA-33-4533, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.7 years (28,001 days).
Specimen TCGA-33-4533-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.4a2fb8b9-0def-4bfa-a40c-b40e8c6161c5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-4533-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7e09db3-5d1e-41b6-beeb-ad3f1880e1bc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 4,921; copy number 3: 13,188; copy number 4: 26,535; copy number 5: 6,213; copy number 6: 6,543; copy number 7: 14; copy number 9: 688; copy number 10: 48; copy number 11: 1,180; copy number 12: 238; copy number 14: 160; copy number 15: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-4533-01A-01D-1195-01): tumor purity 0.7, ploidy 4.08, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:178,116,721–178,116,861, 1 gene: RNU1-45P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,403 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,568,117–79,282,124, 76 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:137,998,735–198,222,513, 1,057 genes, copy number 11–15 (broad region; genes not listed).
- chr5:7,707,802–45,895,970, 558 genes, copy number 11 (broad region; genes not listed).
- chr10:42,149,310–81,137,335, 712 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
